CCDI case PBCRKF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/da605c74-bef5-456c-a4e6-9c9e05babd44

Demographics
Sex at birth: male.

Diagnoses (1)
1. Pleomorphic xanthoastrocytoma: ICD-O-3 morphology code: 9424/3; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 9.5 years (3,461 days).

Biospecimens (3 samples)
- Sample 0DXJEJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DXJF3: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DXJHW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
